Somatic mutation profile of tumor specimen TCGA-20-0991-01A (aliquot TCGA-20-0991-01A-03D-0428-01) from TCGA case TCGA-20-0991, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 78.6 years (28,694 days).
Specimen TCGA-20-0991-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60924d5d-ca60-4041-bfbd-15ab113849c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-0991-10A (Blood Derived Normal), aliquot TCGA-20-0991-10A-01D-0428-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e4ec8d6-26c9-45af-96f4-7356f6d8cadf

The open-access MAF lists 148 somatic variants for this specimen: 106 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 39, Frame Shift Ins 4, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 127/309 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.2953C>T p.R985W (on ENST00000372530 / NM_001198934.2; = p.R957W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 349/510 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs144273435, COSV99766444; called by muse, mutect2, varscan2
- ADAMTS4 | c.1458C>G p.H486Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV63490456; called by muse, mutect2
- ADGRB1 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs757292289, COSV60096964; called by muse, mutect2, varscan2
- ANKFY1 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370962910; called by mutect2, varscan2
- APOD | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 132/595 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754030446, COSV58402149; called by muse, mutect2, varscan2
- ARHGAP20 | c.1435A>G p.R479G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV99503516; called by muse, mutect2, varscan2
- ATP13A4 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 73/370 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs996873260, COSV55070623; called by muse, varscan2
- ATP2C2 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 440/522 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99297699; called by mutect2, varscan2
- BMP2K | c.2878G>T p.D960Y | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV99784955; called by muse, mutect2
- BOC | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56350770, COSV56357883; called by muse, mutect2, varscan2
- CCDC62 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 213/509 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as COSV53434379; called by muse, mutect2, varscan2
- CCNB3 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 56/456 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV52074900; called by muse, mutect2, varscan2
- CHML | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100087188; called by muse, mutect2
- COPA | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV54104001; called by muse, varscan2
- CYP2A7 | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV52501398, COSV52501832; called by muse, mutect2, varscan2
- CYP4Z1 | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100497563; called by muse, mutect2
- DHRS2 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1304527729, COSV51632457; called by muse, mutect2, varscan2
- DUSP5 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 111/341 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100851854; called by muse, mutect2, varscan2
- EGR1 | c.1000dup p.H334Pfs*13 | Frame Shift Ins (INS) | VAF 13/87 reads (15%) | catalogued as rs746692720; called by mutect2, varscan2
- EIF3B | c.1085dup p.E363Rfs*18 | Frame Shift Ins (INS) | VAF 29/200 reads (15%) | catalogued as rs764010445; called by mutect2, varscan2
- FAM161B | c.1355G>A p.R452K (on ENST00000651776; = p.R389K on NM_152445.3) | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV54103530, COSV99679653; called by muse, mutect2, varscan2
- FAM222A | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 99/125 reads (79%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.527); catalogued as rs1227587535, COSV62723506; called by muse, mutect2, varscan2
- FANCD2 | c.3146G>A p.G1049E | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV99810839; called by muse, mutect2, varscan2
- FAT2 | c.8194C>G p.P2732A | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as COSV55821699; called by muse, mutect2, varscan2
- FLNB | c.7251A>T p.L2417F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99912406; called by muse, mutect2, varscan2
- FNIP1 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100330341; called by muse, varscan2
- GALNT7 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 132/244 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760374528, COSV99397121; called by mutect2, varscan2
- GLI2 | c.4394G>T p.S1465I (on ENST00000361492 / NM_001374353.1; = p.S1482I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV58044062; called by muse, mutect2, varscan2
- GPRIN2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as rs782738328, COSV65401181; called by muse, mutect2, varscan2
- GRK5 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 113/169 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs557203104, COSV100962951; called by muse, mutect2, varscan2
- H4C5 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs754130463, COSV63486830; called by muse, mutect2, varscan2
- HAUS6 | c.2663A>T p.H888L | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV65840175; called by muse, mutect2, varscan2
- HHATL | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.28); catalogued as rs1339481996, COSV60042088; called by muse, mutect2, varscan2
- HIPK1 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 281/602 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65785366; called by muse, mutect2, varscan2
- HIVEP3 | c.4511C>T p.S1504L | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1470319088, COSV56016975, COSV99913862; called by muse, mutect2
- HOXB3 | c.797dup p.Q267Afs*30 | Frame Shift Ins (INS) | VAF 14/123 reads (11%) | catalogued as rs762955717; called by mutect2, pindel
- IDE | c.2093A>C p.D698A | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV56424125; called by muse, mutect2, varscan2
- IGF1R | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV51411322; called by mutect2, varscan2
- IGF1R | c.2874C>A p.F958L | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51300898, COSV51335622; called by muse, mutect2
- INO80 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100731675; called by muse, mutect2, varscan2
- ISOC2 | c.427G>A p.D143N (on ENST00000425675 / NM_001136201.2; = p.D159N on NM_024710.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as rs1337070849; called by muse, mutect2
- JAKMIP1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 100/788 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV51533007, COSV51538810; called by muse, mutect2, varscan2
- LCT | c.4160C>T p.S1387F | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51549898; called by muse, varscan2
- LDB3 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV53943506, COSV53951508; called by muse, mutect2
- LGR5 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 132/584 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs763124254, COSV99877729; called by muse, varscan2
- LIPG | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.231); catalogued as COSV54296701; called by muse, mutect2, varscan2
- MACC1 | c.2086G>A p.V696I | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1308491345, COSV60543777; called by muse, mutect2, varscan2
- MAST4 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV68238745; called by muse, mutect2
- METTL27 | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV52897496, COSV99936383; called by mutect2, varscan2
- NCKAP5 | c.2168G>C p.R723T | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58450411; called by muse, mutect2, varscan2
- NFE2L1 | c.485dup p.V163Sfs*14 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs773403681; called by mutect2, varscan2
- NOX1 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs769691003, COSV54193967, COSV54195027; called by muse, mutect2
- NUAK2 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.115); catalogued as COSV100904006; called by muse, mutect2
- OBSCN | c.6982G>A p.E2328K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.695); catalogued as COSV99475366; called by muse, mutect2
- PCDHA11 | c.1774A>G p.K592E | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100248976; called by muse, mutect2, varscan2
- PCSK2 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV52735124; called by muse, mutect2, varscan2
- PEX12 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99862099; called by mutect2, varscan2
- PHACTR2 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59855426; called by muse, mutect2, varscan2
- PIKFYVE | c.3182C>T p.T1061I | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100010172; called by mutect2, varscan2
- PLA2G4F | c.2311C>T p.R771C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs376529914; called by muse, mutect2, varscan2
- PRAMEF12 | c.846C>A p.H282Q | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.965); catalogued as COSV100743122; called by muse, mutect2
- PRKAA2 | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1399478568, COSV64804382; called by muse, mutect2, varscan2
- PRKD1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 185/458 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.339); catalogued as COSV59566973; called by muse, mutect2, varscan2
- R3HDM1 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99925960; called by muse, mutect2
- RIMS2 | c.2315T>C p.L772P (on ENST00000666250 / NM_001348490.2; = p.L580P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51690924; called by muse, mutect2, varscan2
- RNF111 | c.2712A>T p.R904S | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV62086923; called by muse, mutect2, varscan2
- RXRG | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717367; called by muse, mutect2
- SART3 | c.1492A>G p.R498G (on ENST00000228284; = p.R480G on NM_014706.4) | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV99933953; called by muse, mutect2, varscan2
- SEC16A | c.4238G>A p.S1413N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV51529809; called by muse, mutect2, varscan2
- SLC13A2 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs202116509; called by muse, mutect2, varscan2
- SLC13A4 | c.1865T>A p.I622N | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100818832; called by muse, mutect2
- SLC5A2 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755101109, COSV57891045; called by muse, mutect2
- SLCO1C1 | c.1443A>T p.K481N | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV56874155; called by muse, varscan2
- SPTBN5 | c.7032C>A p.N2344K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs981956139, COSV58015834; called by muse, mutect2
- STK32A | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100096827; called by muse, mutect2, varscan2
- TASOR2 | c.7086_7087del p.R2363Ifs*20 | Frame Shift Del (DEL) | VAF 23/228 reads (10%) | catalogued as rs770074902; called by pindel, varscan2
- TIAM2 | c.3450G>A p.M1150I | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1376259588, COSV99265254; called by muse, mutect2
- TMC1 | c.1859A>G p.N620S | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs769474449, COSV52777473; called by muse, mutect2, varscan2
- TMEM132B | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.38); catalogued as rs1470319842, COSV54756716; called by muse, mutect2, varscan2
- TMOD3 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57944310; called by muse, mutect2, varscan2
- TNFSF14 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs772372888, COSV55590939; called by muse, mutect2, varscan2
- USH2A | c.7679A>G p.N2560S | Missense Mutation (SNP) | VAF 142/304 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs370155266, COSV100242230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 118/324 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100661378; called by mutect2, varscan2
- WDR62 | c.1994G>A p.C665Y | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99543375; called by muse, mutect2
- ZC3H13 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99667777; called by muse, mutect2
- ZC3H4 | c.2972A>G p.K991R | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53413704; called by muse, mutect2, varscan2
- ZEB2 | c.3635A>G p.D1212G | Missense Mutation (SNP) | VAF 25/399 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs753328374, COSV100355550; called by muse, mutect2
- ZKSCAN1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 671/1140 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs769034538, COSV100164159; called by mutect2, varscan2
- ZMYND10 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV51602355; called by muse, mutect2, varscan2
- ZNF263 | c.205T>C p.W69R | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99526793; called by mutect2, varscan2
- ZNF337 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867357551; called by muse, mutect2
- ZNF436 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100010971; called by muse, mutect2, varscan2
- ZNF496 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs754694981, COSV54182547; called by muse, varscan2
- ZNF570 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57579475; called by muse, mutect2, varscan2
- ZNF572 | c.1250G>C p.C417S | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60002074; called by muse, mutect2, varscan2
- ZNF671 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 153/210 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs897475081, COSV100234922; called by muse, mutect2, varscan2
- CA14 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 16/460 reads (3%) | called by muse, mutect2
- CDKL5 | c.2150G>A p.R717K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- COL6A6 | c.3503A>T p.N1168I | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.023); called by mutect2, varscan2
- CRAMP1 | c.3298T>C p.S1100P | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FAF1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.025); called by mutect2, varscan2
- GPR1 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 47/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NUTM1 | c.938del p.P313Lfs*2 | Frame Shift Del (DEL) | VAF 67/278 reads (24%) | called by mutect2, pindel, varscan2
- PIP5K1A | c.575T>G p.I192S (on ENST00000368888 / NM_001135638.2; = p.I179S on NM_003557.3) | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- TRAJ45 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- ADGRD1 | c.223C>T p.L75= | Silent (SNP) | VAF 112/346 reads (32%) | catalogued as COSV99895945; called by mutect2, varscan2
- CCNB3 | c.1083C>T p.S361= | Silent (SNP) | VAF 58/457 reads (13%) | catalogued as COSV99328735; called by mutect2, varscan2
- CFAP46 | c.6627G>A p.V2209= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99584314; called by muse, mutect2, varscan2
- COL22A1 | c.534C>T p.G178= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs748297644, COSV57342073; called by muse, mutect2, varscan2
- CRCT1 | c.225C>T p.C75= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV57500658; called by muse, mutect2, varscan2
- EHMT2 | c.1854T>G p.L618= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV64996394; called by muse, mutect2, varscan2
- EXT1 | c.453G>A p.A151= | Silent (SNP) | VAF 30/304 reads (10%) | catalogued as rs780843781, COSV65477606, COSV65480929; called by muse, mutect2
- FLI1 | c.996C>T p.Y332= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs752016751, COSV55643083; ClinVar: likely benign; called by muse, mutect2, varscan2
- GALNT16 | c.1236C>T p.F412= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV61886415; called by muse, mutect2, varscan2
- GLMP | c.312C>T p.P104= | Silent (SNP) | VAF 50/390 reads (13%) | catalogued as rs151318535; called by muse, mutect2, varscan2
- GPX8 | c.408C>T p.I136= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV99696684; called by muse, mutect2, varscan2
- HELB | c.2496G>A p.L832= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as COSV99921698; called by muse, mutect2, varscan2
- HERPUD2 | c.276C>G p.P92= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV60945611; called by muse, varscan2
- INTS4 | c.1263C>T p.N421= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs775194729, COSV71088961; called by muse, mutect2, varscan2
- KRT15 | c.1308C>T p.F436= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV99562955; called by muse, varscan2
- LARP7 | c.1305G>A p.R435= | Silent (SNP) | VAF 36/243 reads (15%) | catalogued as COSV60521262, COSV60521422; called by muse, mutect2, varscan2
- LPO | c.609G>A p.L203= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV99228583; called by muse, mutect2
- LRP2 | c.3888C>T p.C1296= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs138030034; called by muse, mutect2
- NEUROD4 | c.315C>T p.D105= | Silent (SNP) | VAF 35/230 reads (15%) | catalogued as rs145283816; called by muse, mutect2, varscan2
- OR13C8 | c.738A>C p.T246= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV58611405; called by muse, mutect2, varscan2
- PDE9A | c.162G>A p.L54= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV99371254; called by muse, varscan2
- PLCB4 | c.499A>C p.R167= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV53805176, COSV53808908; called by muse, mutect2, varscan2
- POSTN | c.1335C>T p.N445= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as rs1318515416, COSV65711900; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1803G>A p.E601= | Silent (SNP) | VAF 35/272 reads (13%) | catalogued as COSV52863033; called by muse, mutect2
- RBM45 | c.438C>T p.I146= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs144678998; called by muse, mutect2, varscan2
- RNF150 | c.498C>T p.I166= | Silent (SNP) | VAF 95/640 reads (15%) | catalogued as rs777453556, COSV60792445; called by muse, mutect2, varscan2
- RNF220 | c.936G>A p.Q312= | Silent (SNP) | VAF 16/520 reads (3%) | catalogued as COSV100131926; called by muse, mutect2
- SAR1A | c.456G>A p.G152= | Silent (SNP) | VAF 23/319 reads (7%) | catalogued as COSV100951550, COSV64698343; called by muse, mutect2
- SLC45A4 | c.1674C>T p.V558= (on ENST00000517878 / NM_001286646.2; = p.V507= on NM_001080431.2) | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV50133110; called by muse, varscan2
- SOGA3 | c.1971G>A p.E657= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV64107057; called by muse, mutect2, varscan2
- SP1 | c.1740A>T p.A580= (on ENST00000327443 / NM_138473.3; = p.A573= on NM_003109.1) | Silent (SNP) | VAF 41/182 reads (23%) | catalogued as COSV59403566; called by muse, mutect2, varscan2
- STAT6 | c.21C>T p.V7= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV55671712; called by muse, mutect2, varscan2
- STX4 | c.351C>T p.S117= | Silent (SNP) | VAF 12/233 reads (5%) | called by muse, mutect2
- TRHDE | c.1500C>T p.D500= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs748939724, COSV53837777; called by muse, varscan2
- UEVLD | c.786C>T p.Y262= | Silent (SNP) | VAF 18/159 reads (11%) | called by mutect2, varscan2
- WDR44 | c.223C>T p.L75= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as COSV99561378; called by muse, mutect2, varscan2
- XPO6 | c.2871C>T p.T957= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs777598981, COSV58967519; called by muse, mutect2, varscan2
- ZNF222 | c.1305G>A p.K435= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99496193; called by muse, mutect2
- ZPLD1 | c.1203C>T p.P401= (on ENST00000466937 / NM_001329788.1; = p.P417= on NM_175056.2) | Silent (SNP) | VAF 31/498 reads (6%) | called by muse, mutect2
- CACNA1A | c.5547-1254A>T | Intron (SNP) | VAF 44/486 reads (9%) | catalogued as COSV100801718; called by muse, mutect2
- MIR519A1 | n.14A>C | RNA (SNP) | VAF 426/788 reads (54%) | catalogued as rs749096745; called by muse, varscan2
- RBM44 | chr2:237813643 G>C | 5'Flank (SNP) | VAF 12/111 reads (11%) | catalogued as COSV100389871, COSV57630318; called by muse, mutect2, varscan2
